Somatic mutation profile of tumor specimen 0D9MKF from CCDI case PBBIVB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.9 years (5,064 days).
Specimen 0D9MKF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d8420fa-3c3a-4fe7-9c47-f73d797ee63b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9MKG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/984e55c9-cb54-4817-b1b0-f27843361e0a

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Frame Shift Del 10, Silent 10, Nonsense Mutation 3, 5'UTR 2, Splice Region 1, Splice Site 1, 3'UTR 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 157/387 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV64731793, COSV64731830, COSV64732212; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 407/825 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- PDGFRA | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 295/737 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57264163, COSV57266901, COSV57267810; called by muse, mutect2, varscan2
- AOX1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 153/918 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs540242322, COSV65983610; called by muse, mutect2, varscan2
- ARID1A | c.6619C>T p.Q2207* | Nonsense Mutation (SNP) | VAF 81/561 reads (14%) | catalogued as COSV61374784; called by muse, mutect2, varscan2
- ATP10B | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 254/625 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748872879; called by muse, mutect2, varscan2
- CCDC7 | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.184); catalogued as rs41307551, COSV56554941; called by muse, mutect2, varscan2
- CCNF | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 160/552 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs532898317; called by muse, mutect2, varscan2
- CEND1 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 391/819 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.729); catalogued as rs144988066; called by muse, mutect2, varscan2
- CNTN5 | c.2832del p.L945Yfs*6 | Frame Shift Del (DEL) | VAF 220/530 reads (42%) | catalogued as COSV54293987; called by mutect2, varscan2
- CTAGE1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 209/482 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs377367059; called by muse, mutect2, varscan2
- DDX46 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 37/774 reads (5%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs748215709, COSV62799999; called by muse, mutect2
- DNAH9 | c.7823G>A p.R2608H | Missense Mutation (SNP) | VAF 380/773 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766593497, COSV99306951; called by muse, mutect2, varscan2
- ERN2 | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 598/936 reads (64%) | catalogued as rs755206735, COSV55622362; called by muse, mutect2, varscan2
- ESR2 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 338/757 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs764756707, COSV99962787; called by muse, mutect2, varscan2
- FAM184B | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 80/886 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1160276217, COSV99401210; called by muse, mutect2
- FBXL22 | c.65_67del p.S22del | In Frame Del (DEL) | VAF 150/355 reads (42%) | catalogued as rs757568276; called by mutect2, varscan2
- FBXL6 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 71/516 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373864781; called by muse, mutect2, varscan2
- GSDMC | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 42/773 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs375510820; called by muse, mutect2
- LGI3 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 282/546 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs369474754; called by muse, varscan2
- MTUS2 | c.3565C>T p.R1189W (on ENST00000612955 / NM_001366650.1; = p.R168W on NM_015233.6) | Missense Mutation (SNP) | VAF 219/562 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753762677, COSV60158423; called by muse, mutect2, varscan2
- MYRIP | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 116/736 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs771346658, COSV56873806; called by muse, mutect2, varscan2
- NARF | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 274/566 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as rs112135768; called by muse, mutect2, varscan2
- PCDHA10 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 124/273 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as COSV56516596; called by muse, mutect2, varscan2
- PCSK7 | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 74/336 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1393444228; called by muse, mutect2, varscan2
- PLEC | c.7574G>A p.R2525H (on ENST00000322810 / NM_201380.4; = p.R2415H on NM_000445.5) | Missense Mutation (SNP) | VAF 36/744 reads (5%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs372811597; called by muse, mutect2
- SLCO6A1 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 260/559 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.061); catalogued as rs764746269, COSV65814129; called by muse, mutect2, varscan2
- SYCP2L | c.1440+1G>A p.X480_splice | Splice Site (SNP) | VAF 28/506 reads (6%) | catalogued as rs374503829; called by muse, mutect2
- TERB1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 27/634 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.046); catalogued as rs200317788; called by muse, mutect2
- TRRAP | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 135/327 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs148101267; called by muse, mutect2, varscan2
- XYLT1 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 42/1200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54488199; called by muse, mutect2
- ALX3 | c.961_962del p.K321Vfs*167 | Frame Shift Del (DEL) | VAF 158/860 reads (18%) | called by mutect2, varscan2
- CEP104 | c.2151+5G>A | Splice Region (SNP) | VAF 333/748 reads (45%) | called by muse, mutect2
- FBXW7 | c.1590_1591del p.E531Nfs*11 (on ENST00000281708 / NM_001349798.2; = p.E451Nfs*11 on NM_018315.5) | Frame Shift Del (DEL) | VAF 252/526 reads (48%) | called by mutect2, varscan2
- HAUS2 | c.333_334del p.R112Tfs*13 | Frame Shift Del (DEL) | VAF 156/390 reads (40%) | called by mutect2, varscan2
- IL17RE | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 21/673 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- KCNJ8 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 43/912 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); called by muse, mutect2
- MROH2B | c.1641C>A p.D547E | Missense Mutation (SNP) | VAF 310/678 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4X2 | c.306_307del p.E103Dfs*10 | Frame Shift Del (DEL) | VAF 266/530 reads (50%) | called by mutect2, varscan2
- PGAP1 | c.1559del p.I520Kfs*17 | Frame Shift Del (DEL) | VAF 20/122 reads (16%) | called by mutect2, varscan2
- PLXNA3 | c.5080T>C p.F1694L | Missense Mutation (SNP) | VAF 22/511 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PRKD3 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 262/586 reads (45%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PYGO1 | c.722_723del p.F241Yfs*9 | Frame Shift Del (DEL) | VAF 242/620 reads (39%) | called by mutect2, varscan2
- RXFP1 | c.315_316del p.C106Pfs*6 | Frame Shift Del (DEL) | VAF 280/646 reads (43%) | called by mutect2, varscan2
- SETD1B | c.598del p.Q200Rfs*15 | Frame Shift Del (DEL) | VAF 338/722 reads (47%) | called by mutect2, varscan2
- SETD2 | c.5287_5290del p.Q1764Pfs*3 | Frame Shift Del (DEL) | VAF 222/396 reads (56%) | called by mutect2, varscan2
- SSTR1 | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 244/489 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TAF1L | c.3739C>T p.Q1247* | Nonsense Mutation (SNP) | VAF 132/1322 reads (10%) | called by muse, mutect2
- CLSTN2 | c.1494C>T p.G498= | Silent (SNP) | VAF 347/763 reads (45%) | catalogued as rs185070184, COSV101515430, COSV101515637; called by muse, mutect2, varscan2
- EYS | c.3447T>C p.C1149= | Silent (SNP) | VAF 45/297 reads (15%) | catalogued as rs192254604; called by muse, mutect2, varscan2
- GOLGA6D | c.1542G>A p.A514= | Silent (SNP) | VAF 56/291 reads (19%) | catalogued as rs1265546673; called by muse, mutect2, varscan2
- GRIN2A | c.72C>T p.S24= | Silent (SNP) | VAF 549/847 reads (65%) | called by muse, mutect2, varscan2
- HECW1 | c.2172C>T p.S724= | Silent (SNP) | VAF 25/1002 reads (2%) | catalogued as COSV67822025; called by muse, mutect2
- MEOX2 | c.63G>A p.P21= | Silent (SNP) | VAF 202/947 reads (21%) | catalogued as COSV56287897; called by muse, mutect2, varscan2
- PRR12 | c.60G>A p.P20= (on ENST00000615927; = p.P841= on NM_020719.3) | Silent (SNP) | VAF 184/392 reads (47%) | catalogued as COSV69820573; called by mutect2, varscan2
- SHROOM2 | c.381C>T p.P127= | Silent (SNP) | VAF 435/453 reads (96%) | catalogued as rs748449075, COSV101098146; called by muse, mutect2, varscan2
- SMC1B | c.2322C>T p.D774= | Silent (SNP) | VAF 98/263 reads (37%) | catalogued as rs367753850; called by muse, mutect2, varscan2
- UGT2B7 | c.861C>A p.P287= | Silent (SNP) | VAF 274/647 reads (42%) | called by muse, mutect2, varscan2
- BAIAP2L1 | c.1163+24C>T | Intron (SNP) | VAF 173/365 reads (47%) | catalogued as rs374666080; called by muse, mutect2, varscan2
- OR2H2 | c.*26_*27del | 3'UTR (DEL) | VAF 46/267 reads (17%) | called by mutect2, varscan2
- RNF32 | c.-4C>T | 5'UTR (SNP) | VAF 263/611 reads (43%) | catalogued as COSV100311452; called by muse, mutect2, varscan2
- TNIP3 | c.-105T>C | 5'UTR (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
